Somatic mutation profile of tumor specimen 0DMN2C from CCDI case PBCAMK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 6.5 years (2,356 days).
Specimen 0DMN2C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b943a1c7-439d-423d-b52f-b262946243ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMN18 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ca2b6da-ae90-42a8-932f-6d9cf4d1c32a

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLPTM1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 137/324 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.087); catalogued as rs192663448, COSV61611966; called by muse, mutect2, varscan2
- FSHB | c.299G>T p.C100F | Missense Mutation (SNP) | VAF 218/476 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99569506; called by muse, mutect2, varscan2
- VILL | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 251/498 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as rs372280053; called by muse, mutect2, varscan2
- NHSL1 | c.2611G>A p.V871M | Missense Mutation (SNP) | VAF 220/493 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- SYT17 | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 228/498 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- P4HA1 | c.580C>T p.L194= | Silent (SNP) | VAF 271/537 reads (50%) | called by muse, mutect2, varscan2
- DOK5 | c.*52C>G | 3'UTR (SNP) | VAF 192/446 reads (43%) | called by muse, mutect2, varscan2
